Gene-level copy-number profile of tumor specimen C3L-00583-02 from CPTAC case C3L-00583, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.4 years (20,237 days).
Specimen C3L-00583-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ccc9c63b-f0b9-4b5d-a578-29d283f890db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00583-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f8659ae0-3e86-4d0b-bd2f-4b5bfc0432df

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 37,648; copy number 2: 17,962; copy number 3: 2,783.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 2,782 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–686,673, 20 genes, copy number 3 (within-gene range 2–4): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr5:58,198–58,915, 1 gene, copy number 3: AC113430.1.
- chr7:7,550,104–102,434,780, 1,677 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr7:102,456,238–159,233,377, 1,076 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr10:102,914,585–102,915,404, 1 gene, copy number 3: AL356608.1.
- chr12:12,310–38,133, 3 genes, copy number 3: DDX11L8, WASH8P, FAM138D.
- chr12:133,217,210–133,238,549, 4 genes, copy number 3: AC226150.1, ANHX, RNU6-717P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 35,313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
